MMRF case MMRF_2333 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8d1ca468-24e1-4469-ba23-a01cb2142dd4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.0 years (29,589 days); Days to last known disease status: 698 days (1.9 years); Days to last follow up: 698 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 0): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 66.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 4.48 g/L; Immunoglobulin A 27 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 29 g/L; Total Protein 9 g/dL; Glucose 7.92 mmol/L.
- Day 120: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 9.22 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.83 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 3.91 mmol/L.
- Day 175: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 8.43 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.58 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 5.23 mmol/L.
- Day 263 (ECOG 1): M Protein 0 g/dL; Hemoglobin 6.63 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 372: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.77 g/L; Immunoglobulin M 0.91 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 4.79 mmol/L.
- Day 428 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin A 2.58 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 547 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 3.03 g/L; Immunoglobulin M 0.99 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Albumin 37.1 g/L; Total Protein 6.8 g/dL; Glucose 4.07 mmol/L.
- Day 645: Hemoglobin 6.45 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 33 g/L; Total Protein 7 g/dL; Glucose 5.89 mmol/L.
- Day 698: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 1.18 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 7.3 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -14: Weight: 63 kg; Height: 164 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_2333_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_2333_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
